Somatic mutation profile of tumor specimen C3N-02190-01 (aliquot CPT0205450007) from CPTAC case C3N-02190, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.5 years (19,534 days).
Specimen C3N-02190-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ca8c96b-cbc1-4430-8d90-2a04e50af876.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02190-71 (Blood Derived Normal), aliquot CPT0205510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b00bcbe-a549-458a-9e55-4f134e09a993

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 9, Intron 3, Frame Shift Del 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 12/57 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASXL3 | c.6328G>A p.E2110K | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99324886; called by muse, mutect2, varscan2
- BTNL2 | c.1255G>A p.V419M | Missense Mutation (SNP) | VAF 60/297 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs554112033, COSV66630214; called by muse, mutect2, varscan2
- CSAD | c.-91+5G>A | Splice Region (SNP) | VAF 16/114 reads (14%) | catalogued as rs758172438; called by muse, mutect2, varscan2
- FLT4 | c.1736A>T p.Q579L | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV56112610; called by muse, mutect2, varscan2
- KIR3DL3 | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 99/479 reads (21%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.88); catalogued as rs564097015; called by muse, mutect2, varscan2
- P4HA2 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs200144298, COSV51333166; called by muse, mutect2, varscan2
- PKHD1 | c.5707G>A p.V1903I | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs753639079, COSV61884120, COSV61891662; called by muse, mutect2, varscan2
- SPTA1 | c.5041G>A p.V1681I | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs371655531; called by muse, mutect2
- TANC2 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767201600, COSV67332585; called by muse, mutect2, varscan2
- TMEM70 | c.680C>A p.P227Q | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.354); catalogued as rs1285682769; called by muse, mutect2
- ZDHHC16 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 99/246 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs765232890; called by muse, mutect2, varscan2
- AVPR1A | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 88/304 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- C4orf54 | c.2098del p.A700Pfs*55 | Frame Shift Del (DEL) | VAF 62/272 reads (23%) | called by mutect2, pindel, varscan2
- CCDC180 | c.2698C>T p.Q900* | Nonsense Mutation (SNP) | VAF 38/131 reads (29%) | called by muse, mutect2, varscan2
- CCPG1 | c.1769A>G p.N590S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH12 | c.6125T>C p.I2042T (on ENST00000351747; = p.I2061T on NM_001366028.2) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EXTL3 | c.1790T>A p.V597D | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FCRL1 | c.18G>T p.L6F | Missense Mutation (SNP) | VAF 60/277 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- MAP2K4 | c.500C>A p.A167E | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MMEL1 | c.2084T>C p.M695T | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MYCBP2 | c.11195A>G p.E3732G (on ENST00000357337; = p.E3770G on NM_015057.5) | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PCDH11Y | c.3481G>A p.A1161T | Missense Mutation (SNP) | VAF 238/432 reads (55%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRKCB | c.1591C>A p.L531M | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTPRN2 | c.2099G>A p.G700E | Missense Mutation (SNP) | VAF 95/478 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RAB36 | c.341G>C p.R114T | Missense Mutation (SNP) | VAF 88/377 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.25); called by muse, varscan2
- SGCZ | c.577G>C p.V193L | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SNAP47 | c.392G>C p.S131T | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- TRIM60 | c.1253T>C p.F418S | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF250 | c.847C>A p.H283N | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ANKRD30A | c.3123C>T p.A1041= (on ENST00000611781; = p.A985= on NM_052997.2) | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs564020781, COSV100654618; called by muse, mutect2, varscan2
- ARRDC2 | c.126G>A p.A42= | Silent (SNP) | VAF 129/524 reads (25%) | catalogued as COSV55843908; called by muse, mutect2, varscan2
- COL22A1 | c.2322G>A p.G774= | Silent (SNP) | VAF 52/203 reads (26%) | catalogued as COSV57327086; called by muse, mutect2, varscan2
- FCGR2A | c.669C>T p.V223= (on ENST00000271450 / NM_001136219.3; = p.V222= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/223 reads (26%) | called by muse, mutect2, varscan2
- FOXP2 | c.1413T>C p.N471= | Silent (SNP) | VAF 62/340 reads (18%) | called by muse, mutect2, varscan2
- NOBOX | c.1014C>T p.L338= | Silent (SNP) | VAF 25/185 reads (14%) | catalogued as rs780102886; called by muse, mutect2, varscan2
- PLPPR3 | c.994C>T p.L332= (on ENST00000520876 / NM_001270366.2; = p.L360= on NM_024888.2) | Silent (SNP) | VAF 69/233 reads (30%) | called by muse, mutect2, varscan2
- SLC26A3 | c.537G>A p.A179= | Silent (SNP) | VAF 73/477 reads (15%) | catalogued as rs374927524; called by muse, mutect2, varscan2
- TCHH | c.3162G>A p.E1054= | Silent (SNP) | VAF 74/347 reads (21%) | catalogued as rs752160625; called by muse, varscan2
- GAK | c.268-328C>T | Intron (SNP) | VAF 59/317 reads (19%) | catalogued as rs750994566; called by muse, mutect2, varscan2
- NCF4 | c.759-100C>G | Intron (SNP) | VAF 211/611 reads (35%) | catalogued as COSV50627639; called by muse, mutect2, varscan2
- VPS50 | c.660-17_660-16insG | Intron (INS) | VAF 3/34 reads (9%) | catalogued as rs746280864; called by pindel, varscan2
